Somatic mutation profile of tumor specimen TCGA-K4-A5RI-01A (aliquot TCGA-K4-A5RI-01A-11D-A289-08) from TCGA case TCGA-K4-A5RI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.4 years (24,614 days).
Specimen TCGA-K4-A5RI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7112fbb-a82f-409c-ab07-a60ca97e3dbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A5RI-10A (Blood Derived Normal), aliquot TCGA-K4-A5RI-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6381f6dd-8141-4806-af2e-ab11b81d4516

The open-access MAF lists 153 somatic variants for this specimen: 109 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 39, Nonsense Mutation 8, Intron 4, Frame Shift Ins 4, Frame Shift Del 3, Splice Region 2, Splice Site 2, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 41/47 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 46/68 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- USP11 | c.1599G>A p.T533= (on ENST00000218348; = p.T490= on NM_001371072.1) | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs777516785, COSV54472648, COSV99511021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.2014C>A p.P672T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV51930332; called by muse, mutect2, varscan2
- ANK2 | c.8509G>C p.A2837P | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.241); catalogued as COSV52148025; called by muse, mutect2, varscan2
- APBB1IP | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV66130623, COSV66130669, COSV66130705; called by muse, mutect2, varscan2
- ARHGAP35 | c.1790G>C p.R597T | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV101351687, COSV68329418; called by muse, mutect2, varscan2
- ARIH2 | c.524A>C p.D175A | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.351); catalogued as COSV62703933; called by muse, mutect2, varscan2
- ASPM | c.742T>C p.S248P | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54125367; called by muse, mutect2, varscan2
- BBX | c.2590A>G p.K864E (on ENST00000325805 / NM_001142568.3; = p.K834E on NM_020235.7) | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.888); catalogued as COSV57879681; called by muse, mutect2, varscan2
- C1orf112 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53676929, COSV53679825; called by muse, mutect2, varscan2
- CDH3 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375040740, COSV50555079; called by muse, mutect2, varscan2
- CDH7 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100543285, COSV59882200; called by muse, mutect2, varscan2
- CELSR2 | c.3142C>T p.R1048* | Nonsense Mutation (SNP) | VAF 16/166 reads (10%) | catalogued as rs775244724, COSV99604704; called by muse, mutect2
- CLSPN | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV52047393; called by muse, mutect2
- CTBS | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55361313; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- CXorf65 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52147331; called by muse, mutect2, varscan2
- DUXA | c.438A>C p.Q146H | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV73729520; called by muse, mutect2
- EGR2 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 77/103 reads (75%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs759547856, COSV54346263; called by muse, mutect2, varscan2
- ERAS | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.737); catalogued as COSV54432532; called by muse, mutect2, varscan2
- FAM47B | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV61452653; called by muse, mutect2, varscan2
- FAM47C | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs781884172, COSV63723626; called by muse, mutect2, varscan2
- FAT4 | c.12822G>T p.K4274N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58673232; called by muse, mutect2, varscan2
- FIGN | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 90/116 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60763528; called by muse, mutect2, varscan2
- FLNA | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 135/241 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV61038194; called by muse, mutect2, varscan2
- GINM1 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66389471; called by muse, mutect2, varscan2
- GREM2 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs922021547, COSV58947070; called by muse, mutect2, varscan2
- GRIK5 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV53475450; called by muse, mutect2, varscan2
- HCN1 | c.2054C>A p.T685K | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.115); catalogued as COSV57495586; called by muse, mutect2, varscan2
- HECTD1 | c.4990G>T p.D1664Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67945256; called by muse, mutect2, varscan2
- HK1 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 66/98 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53853869; called by muse, varscan2
- HK1 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 81/128 reads (63%) | SIFT tolerated (0.49); PolyPhen benign (0.154); catalogued as COSV53853915; called by muse, varscan2
- HK1 | c.1572G>A p.E524= | Splice Region (SNP) | VAF 98/145 reads (68%) | catalogued as COSV53853958; called by muse, mutect2, varscan2
- IAPP | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.433); catalogued as COSV53713077; called by muse, mutect2, varscan2
- IFIH1 | c.1552A>G p.I518V | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs747683934, COSV55124860; called by muse, mutect2, varscan2
- IFT52 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs1167772313, COSV65974508; called by muse, mutect2
- IMPG1 | c.667-2A>G p.X223_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV64054575; called by muse, mutect2, varscan2
- IRX1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.456); catalogued as rs752014452, COSV57358212; called by muse, mutect2, varscan2
- KATNIP | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs777648421, COSV55174372; called by muse, mutect2, varscan2
- KIAA1549L | c.980C>T p.P327L (on ENST00000321505; = p.P624L on NM_012194.3) | Missense Mutation (SNP) | VAF 132/204 reads (65%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55770106; called by muse, mutect2, varscan2
- KMT2D | c.16390A>C p.T5464P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56414391; called by muse, mutect2, varscan2
- KMT2D | c.15341A>G p.H5114R | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56414410, COSV56483931; called by muse, mutect2, varscan2
- LATS1 | c.3144G>A p.W1048* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99486678; called by muse, mutect2, varscan2
- MDM2 | c.1489C>G p.P497A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV50697934, COSV99254778; called by muse, mutect2
- MED16 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99516259; called by muse, mutect2, varscan2
- MEX3B | c.962dup p.S322* | Frame Shift Ins (INS) | VAF 44/168 reads (26%) | catalogued as rs745465397; called by mutect2, pindel, varscan2
- MRPL44 | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV51312287; called by muse, mutect2
- MSH4 | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as rs766799660, COSV54196161, COSV99592531; called by muse, mutect2, varscan2
- MUC16 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs367716629; called by muse, mutect2, varscan2
- MYH4 | c.5758C>T p.Q1920* | Nonsense Mutation (SNP) | VAF 65/112 reads (58%) | catalogued as COSV99702224; called by muse, mutect2, varscan2
- NLE1 | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62603753; called by muse, mutect2
- NR4A3 | c.501C>G p.I167M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58243498; called by muse, varscan2
- NRDC | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV61401920; called by muse, mutect2, varscan2
- OLFM3 | c.505T>A p.L169I (on ENST00000338858 / NM_001288821.1; = p.L149I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV58796139; called by muse, mutect2, varscan2
- OR2L3 | c.938A>G p.*313Wext*28 | Nonstop Mutation (SNP) | VAF 38/72 reads (53%) | catalogued as rs1429370360, COSV63456610; called by muse, mutect2, varscan2
- OR4C11 | c.515T>A p.I172N | Missense Mutation (SNP) | VAF 61/74 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56352323; called by muse, mutect2, varscan2
- OR52E8 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 79/133 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66205027; called by muse, mutect2, varscan2
- OSBPL8 | c.465A>C p.L155F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53878808; called by muse, mutect2, varscan2
- PARD6A | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54666076, COSV54669405; called by muse, mutect2
- PCCB | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 84/372 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); catalogued as rs2228310, COSV52443591; called by muse, mutect2, varscan2
- PCDH11X | c.3902C>G p.T1301R | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53445649; called by muse, mutect2, varscan2
- PCDHA6 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 101/141 reads (72%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as rs782487048, COSV65342166; called by muse, mutect2, varscan2
- PCDHB16 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV53358433; called by muse, mutect2
- PCLO | c.4548T>A p.S1516R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV61617969; called by muse, mutect2, varscan2
- PDIA6 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55349391; called by muse, mutect2, varscan2
- PIK3AP1 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.677); catalogued as COSV59530682, COSV59531146; called by muse, mutect2
- PLCL1 | c.530A>T p.N177I | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV70821936; called by muse, mutect2
- PPP2R5E | c.450C>G p.H150Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61740709; called by muse, mutect2, varscan2
- RADIL | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs1211162769, COSV68199481; called by muse, mutect2, varscan2
- RASGRP2 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 66/87 reads (76%) | catalogued as COSV100818351; called by muse, mutect2, varscan2
- RBAK | c.1608G>C p.E536D | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV62330823; called by muse, varscan2
- RBAK | c.1776G>C p.E592D | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV62330834; called by muse, mutect2, varscan2
- RBAK | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as COSV62330839; called by muse, mutect2, varscan2
- RBP3 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.499); catalogued as rs782332883; called by muse, mutect2, varscan2
- RCN2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV58031048; called by muse, mutect2, varscan2
- RPA2 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as COSV57876970; called by muse, mutect2, varscan2
- RTKN | c.1033C>T p.P345S (on ENST00000272430 / NM_001015055.2; = p.P332S on NM_033046.2) | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV51961597; called by muse, mutect2, varscan2
- RTN1 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99956842; called by mutect2, varscan2
- SAMHD1 | c.1411-11_1415del p.X471_splice | Splice Site (DEL) | VAF 32/110 reads (29%) | catalogued as COSV53428432; called by mutect2, pindel, varscan2
- SERPINI2 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.583); catalogued as COSV52984460; called by muse, mutect2, varscan2
- SLC7A6 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as COSV99546832; called by muse, mutect2, varscan2
- SLITRK5 | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61521221; called by muse, mutect2, varscan2
- SOX14 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60162497; called by muse, mutect2, varscan2
- SPSB4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs1457468003, COSV100141745; called by muse, mutect2
- SPTBN5 | c.8534C>T p.A2845V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as rs1385801506, COSV100312161; called by muse, mutect2
- SPTBN5 | c.8533G>C p.A2845P | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.786); catalogued as COSV100312163; called by muse, mutect2
- STAT1 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV63115142; called by muse, mutect2, varscan2
- STATH | c.105T>C p.Y35= | Splice Region (SNP) | VAF 12/112 reads (11%) | catalogued as rs112579213, COSV99887328; called by muse, mutect2
- SYNE2 | c.2522C>T p.S841L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.251); catalogued as rs1483737214, COSV59940986; called by muse, mutect2, varscan2
- TEP1 | c.3070C>G p.Q1024E | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV52988559; called by muse, mutect2, varscan2
- THSD7A | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV70260842; called by muse, mutect2, varscan2
- TMEM50B | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV70278948; called by muse, mutect2, varscan2
- TNN | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV53422239; called by muse, mutect2, varscan2
- TNS1 | c.2899A>T p.S967C | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV50691656; called by muse, mutect2, varscan2
- TRIML1 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV60193475; called by muse, mutect2
- TRPS1 | c.2753A>T p.N918I (on ENST00000220888 / NM_001330599.2; = p.N931I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/203 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55228154, COSV55258311; called by muse, mutect2, varscan2
- VEPH1 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV62876337; called by muse, mutect2, varscan2
- WNT2B | c.410G>A p.R137Q (on ENST00000369684 / NM_024494.3; = p.R118Q on NM_004185.4) | Missense Mutation (SNP) | VAF 84/147 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775324743, COSV56672776; called by muse, mutect2, varscan2
- XPNPEP3 | c.1159A>T p.M387L | Missense Mutation (SNP) | VAF 111/329 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV63210047; called by muse, mutect2, varscan2
- ZBTB16 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs755612134, COSV60089610; called by muse, mutect2, varscan2
- ZNF124 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61506868; called by muse, mutect2, varscan2
- ZNF644 | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV61346179; called by muse, mutect2, varscan2
- ZNF846 | c.1242G>T p.R414S | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV67411817, COSV67412869; called by muse, mutect2, varscan2
- MRC2 | c.1043del p.N348Tfs*31 | Frame Shift Del (DEL) | VAF 45/169 reads (27%) | called by mutect2, pindel, varscan2
- MYOCD | c.334dup p.I112Nfs*29 | Frame Shift Ins (INS) | VAF 77/236 reads (33%) | called by mutect2, pindel, varscan2
- RIPK1 | c.1550dup p.M517Ifs*11 | Frame Shift Ins (INS) | VAF 41/127 reads (32%) | called by mutect2, pindel, varscan2
- YTHDF1 | c.859dup p.Q287Pfs*62 | Frame Shift Ins (INS) | VAF 81/171 reads (47%) | called by mutect2, pindel, varscan2
- ZNF117 | c.924del p.E309Nfs*45 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- ZNF544 | c.1547del p.G516Efs*76 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.3093C>T p.T1031= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV56979887; called by muse, mutect2, varscan2
- ADAMTS7 | c.4212C>A p.P1404= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV66306087; called by muse, mutect2, varscan2
- ADCK5 | c.843G>A p.E281= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs782191036, COSV100450711; called by muse, mutect2, varscan2
- AGAP2 | c.2331C>T p.S777= (on ENST00000547588 / NM_001122772.2; = p.S441= on NM_014770.4) | Silent (SNP) | VAF 54/231 reads (23%) | catalogued as COSV57726997; called by muse, mutect2, varscan2
- ATP5MC2 | c.321T>C p.S107= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV58600965; called by muse, mutect2, varscan2
- C3orf56 | c.354G>T p.P118= | Silent (SNP) | VAF 144/597 reads (24%) | catalogued as COSV67756017; called by muse, mutect2, varscan2
- CACNG6 | c.684C>T p.G228= (on ENST00000252729 / NM_145814.1; = p.G157= on NM_031897.2) | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV53165822; called by muse, mutect2, varscan2
- CDH6 | c.81G>A p.R27= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as COSV54064983, COSV54072492; called by muse, mutect2
- CENPK | c.528C>G p.L176= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV54467377; called by muse, mutect2, varscan2
- CHST15 | c.744C>T p.F248= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as rs1317165549, COSV60560520; called by muse, mutect2, varscan2
- CLCA1 | c.1161C>T p.S387= | Silent (SNP) | VAF 78/174 reads (45%) | catalogued as rs111337245; called by muse, mutect2, varscan2
- CTIF | c.1743G>A p.L581= | Silent (SNP) | VAF 49/144 reads (34%) | catalogued as COSV56480339; called by muse, mutect2, varscan2
- DIP2C | c.3750C>G p.L1250= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV55147534; called by muse, varscan2
- FBXL7 | c.1146C>T p.N382= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs746695934, COSV61640788; called by muse, mutect2, varscan2
- HBS1L | c.969A>C p.G323= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV63200109; called by muse, mutect2, varscan2
- KCNH8 | c.465A>G p.R155= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV60457453; called by muse, mutect2, varscan2
- KCNMA1 | c.1038C>G p.L346= | Silent (SNP) | VAF 218/299 reads (73%) | catalogued as COSV54230646; called by muse, mutect2, varscan2
- KIF1A | c.1593G>C p.L531= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV57482762, COSV57483313; called by muse, mutect2, varscan2
- LAMC2 | c.3402C>T p.I1134= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV51452734; called by muse, mutect2, varscan2
- LRRIQ4 | c.301C>T p.L101= | Silent (SNP) | VAF 64/308 reads (21%) | catalogued as rs754651639, COSV61618700; called by muse, mutect2, varscan2
- MAP4K3 | c.747T>C p.F249= | Silent (SNP) | VAF 56/74 reads (76%) | catalogued as COSV55710577; called by muse, varscan2
- MAP7D3 | c.2373A>C p.L791= | Silent (SNP) | VAF 98/382 reads (26%) | catalogued as COSV100286361, COSV60170172; called by muse, mutect2, varscan2
- MYPN | c.3507G>A p.K1169= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100590296, COSV100590622; called by muse, mutect2
- NEDD4L | c.747C>T p.F249= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV56841047; called by muse, mutect2, varscan2
- OPRD1 | c.897G>T p.A299= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV52380351, COSV52382618; called by muse, mutect2, varscan2
- ORAI3 | c.96C>T p.H32= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100591014; called by muse, mutect2, varscan2
- P2RY8 | c.975C>G p.L325= | Silent (SNP) | VAF 110/189 reads (58%) | catalogued as COSV67176784; called by muse, mutect2, varscan2
- PCDH10 | c.1932C>A p.V644= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs747027926, COSV52088239; called by muse, mutect2, varscan2
- PLOD3 | c.612G>A p.L204= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV56181439, COSV56182750, COSV99778051; called by muse, mutect2, varscan2
- RECQL4 | c.2970C>G p.V990= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV56743066; called by muse, mutect2, varscan2
- RSPH6A | c.502A>C p.R168= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV55570220; called by muse, mutect2, varscan2
- SLC6A17 | c.999C>T p.A333= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as rs140501605; called by muse, mutect2, varscan2
- SLITRK2 | c.1692T>C p.H564= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as COSV59423385; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.591T>C p.D197= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV60322020; called by muse, mutect2, varscan2
- THRAP3 | c.726G>C p.L242= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV63566781; called by muse, mutect2
- TLL1 | c.1014A>T p.A338= | Silent (SNP) | VAF 58/180 reads (32%) | catalogued as COSV50262861; called by muse, mutect2, varscan2
- TRIM17 | c.1272C>T p.F424= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as rs148358732; called by muse, mutect2, varscan2
- TULP3 | c.543C>T p.L181= | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as rs1254793493, COSV68117380, COSV68117811; called by muse, varscan2
- AC024598.1 | c.1130-1504G>A | Intron (SNP) | VAF 80/115 reads (70%) | catalogued as rs754001749, COSV60823735; called by muse, mutect2, varscan2
- HTR2C | c.-80+16976A>T | Intron (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99350990; called by muse, mutect2, varscan2
- NRXN1 | c.3719-1436G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs754724604, COSV60486133; called by muse, mutect2, varscan2
- PARP1 | c.287-626G>T | Intron (SNP) | VAF 30/48 reads (63%) | catalogued as COSV100828623; called by muse, mutect2, varscan2
- POLQ | chr3:121546585 T>A | 5'Flank (SNP) | VAF 22/175 reads (13%) | called by muse, varscan2
